Surgical pathology report (de-identified scan), TCGA case TCGA-38-4629, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site UNC, specimen TCGA-38-4629-01A (Primary Tumor).

[page 1 of 2]
Diagnosis:

- : Lung, right upper lobe and contiguous ribs 3 and 4, lobectomy and chest wall resection.
- Adenocarcinoma, poorly differentiated, 5.5 cm diameter, with extension through pleura at site of pleural adhesions; bronchial and final chest wall surgical margins not involved.
- Lymph nodes, peribronchial - No metastatic carcinoma identified (0/1).
- Patchy acute bronchopneumonia with subpleural fibrous plaque in uninvolved lung.

B: Station 7 lymph node, removal.

- No metastatic carcinoma identified (0/3 fragments).

C: Nodule, right middle lobe, wedge biopsy.

- No metastatic carcinoma identified (0/1).

D: R4 lymph nodes, removal.

- No metastatic carcinoma identified (0/9 fragments).

Comment:

None.

Clinical History:

right upper lobe mass, undergoes right thoracosectomy.

Gross Description:

Received are four appropriately containers.

Container A:

Specimen fixation: formalin

Type of specimen/parts of lung received: right lung upper lobe with attached right rib #3 and #4

Size of specimen: 15 x 12 x 4 cm and attached rib and soft tissue measures 11 x 5 x 3.5 cm

Weight of specimen: 530 g

Other attached structures: right #3 and #4 ribs and chest wall soft tissue

Tumor location: tumor is located peripherally of upper portion of the right upper lobe

Tumor size: 5.5 x 3.5 x 3.0 cm, tumor is grossly white/gray and infiltrative involving the pleura and extending to the chest wall

Relationship of tumor to bronchus: tumor is at least 5 cm away from bronchus

Distance of tumor to bronchial margin: at least 5 cm

Relationship/distance of tumor to pleura: tumor grossly invades through the pleura into adjacent chest wall

Distance of tumor to other surgical margins: 2.8 cm from posterior rib resection margin, at least 5 cm away from anterior rib resection margin. The closest to lung resection margin is 3.5 cm.

Presence/absence of satellite tumor nodules: present, one satellite nodule is identified measuring 2.5 x 0.8 x 2.2 cm, grossly it is 2.2 cm away from main tumor mass

Involvement of attached structures by tumor: bronchus, pulmonary resection margin and attached chest wall margin is grossly not involved by tumor

Description of nontumorous lung: post obstructive changes

Block Summary:

- A1 - bronchial and pulmonary vessel margin
- A2,A3 - pulmonary resection margin after removal of surgical staples
- A4-A5 - tumor with involved pleura
- A6-A8 - representative section of the main tumor mass
- A9-A10 - tumor with attached chest wall
- A11 - representative section from satellite nodule
- A12 - anterior chest wall soft tissue resection margin
- A13 - posterior chest wall soft tissue margin
- A14 - two lymph node candidates from hilar region
- A15 - anterior tip margin
- A16 - posterior rib margin
- A17-A18 - tumor with chest wall
- A19 - non-tumoral lung section

[page 2 of 2]
Container B is additionally labeled "station 7". It consists of a brown/black, triangular shaped soft tissue specimen. Bisected and submitted in B1, [REDACTED].

Container C is additionally labeled "right middle nodule". It consists of a black/brown, 0.8 x 0.4 x 0.4 cm nodule. Bisected and submitted in C1, [REDACTED].

Container D is additionally labeled "R4". It holds a 3.4 x 1.5 cm, yellow/black soft tissue fragment. There are nine lymph node candidates identified ranging from 0.3 to 1.1 cm in greatest dimension. All lymph node candidates were submitted in D1-D3.

D1 - four lymph node candidates
D2 - two lymph node candidates
D3 - three lymph node candidates

Light Microscopy:

Light microscopic examination is performed by Dr.

Tumor histologic type (WHO classification): Adenocarcinoma (mucin (+), TTF1 (+), calretinin (-))

Tumor histologic grade (WHO classification): poorly differentiated

Tumor size (greatest dimension): 5.5 cm diameter

Histologic assessment of surgical margins: Bronchial and pulmonary vascular margins not involved, chest wall bone and soft tissue margins not involved.

Pleural involvement: Pleural adhesions are present overlying carcinoma, and pleural involvement is present.
In situ carcinoma: not identified

Invasion:

angiolymphatic - not identified
perineural - not identified

Lymph nodes (by node group): 0/14 total (see diagnoses for locations)

Extracapsular extension of tumor in lymph nodes: n/a

Findings in nontumorous lung:

Patchy acute bronchopneumonia (A8), subpleural fibrous scar with smoking associated changes (A11).

Source: NCI Genomic Data Commons file 2b56b873-dc30-4602-a9af-a608bd720e79 (TCGA-38-4629.9546E974-686D-4D97-B5BD-771972CB4B82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).